CCDI case PBCGEL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2d7d20a7-74ef-4ddf-a7a4-7ab7e00c2d78

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.5 years (6,771 days).

Biospecimens (3 samples)
- Sample 0DR9BT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR9C7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DR9CV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
